Somatic mutation profile of tumor specimen 0DU3KU from CCDI case PBCIJW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.1 years (3,674 days).
Specimen 0DU3KU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf7401f0-df41-4699-bcc8-ebd1b4087b2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3ME (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68dfec25-3e1e-4c31-8164-f00bf82d2df7

The open-access MAF lists 48 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, 3'UTR 4, Intron 3, Frame Shift Del 3, Nonsense Mutation 2, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 229/329 reads (70%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AHNAK2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 155/301 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1437160293, COSV60918612; called by muse, mutect2, varscan2
- ARFGEF3 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 119/310 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs201686105; called by muse, mutect2, varscan2
- C13orf42 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 208/621 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1229165088; called by muse, mutect2, varscan2
- CDHR1 | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs531220625; called by muse, mutect2, varscan2
- NTN4 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.253); catalogued as rs776649804, COSV59217232; called by muse, mutect2, varscan2
- PHEX | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 163/172 reads (95%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.628); catalogued as rs1394418645; called by muse, mutect2, varscan2
- TELO2 | c.936G>A p.T312= | Splice Region (SNP) | VAF 77/143 reads (54%) | catalogued as rs762959262, COSV51978400; called by muse, mutect2, varscan2
- ZNF570 | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57578067; called by muse, varscan2
- AKAP3 | c.1873G>C p.D625H | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- AKAP3 | c.1017G>C p.R339S | Missense Mutation (SNP) | VAF 128/338 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- APOBEC3B | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 123/156 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- CFI | c.1647C>A p.N549K | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- DIP2C | c.2460G>C p.K820N | Missense Mutation (SNP) | VAF 36/413 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- GOLGA5 | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2
- GOT1 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 107/247 reads (43%) | called by muse, mutect2, varscan2
- IFNK | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 369/380 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NOTCH1 | c.6098_6105del p.H2033Rfs*18 | Frame Shift Del (DEL) | VAF 64/263 reads (24%) | called by pindel, varscan2
- NOTCH1 | c.1054_1055insCCCCATG p.D352Afs*3 | Nonsense Mutation (INS) | VAF 51/497 reads (10%) | called by mutect2, pindel
- NOTCH1 | c.448_449dup p.N151Pfs*127 | Frame Shift Ins (INS) | VAF 97/358 reads (27%) | called by mutect2, pindel, varscan2
- OSBP2 | c.2026C>T p.H676Y | Missense Mutation (SNP) | VAF 228/384 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PALD1 | c.2520G>T p.W840C | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.8732G>T p.G2911V | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCUBE3 | c.1736_1738dup p.R579dup | In Frame Ins (INS) | VAF 172/326 reads (53%) | called by mutect2, varscan2
- SHB | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLAIN2 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SLC6A2 | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPHK2 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 110/215 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFP42 | c.85del p.Q29Kfs*12 | Frame Shift Del (DEL) | VAF 52/347 reads (15%) | called by mutect2, pindel, varscan2
- ZNF423 | c.645C>G p.D215E (on ENST00000563137 / NM_001379286.1; = p.D207E on NM_015069.4) | Missense Mutation (SNP) | VAF 141/296 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- AKAP3 | c.654G>A p.L218= | Silent (SNP) | VAF 87/250 reads (35%) | called by muse, mutect2, varscan2
- ASTN2 | c.1212G>A p.E404= (on ENST00000313400 / NM_001365069.1; = p.E353= on NM_014010.5) | Silent (SNP) | VAF 211/462 reads (46%) | catalogued as rs890117363; called by muse, mutect2, varscan2
- DNAJC4 | c.522C>T p.A174= | Silent (SNP) | VAF 150/333 reads (45%) | catalogued as COSV54175814; called by muse, mutect2, varscan2
- FCGBP | c.2352A>T p.P784= | Silent (SNP) | VAF 120/226 reads (53%) | called by muse, mutect2
- KRT36 | c.537G>T p.R179= | Silent (SNP) | VAF 141/313 reads (45%) | catalogued as COSV60202552; called by muse, mutect2, varscan2
- OSBP2 | c.1911C>A p.S637= | Silent (SNP) | VAF 354/534 reads (66%) | called by muse, mutect2, varscan2
- PCDH17 | c.3162G>T p.L1054= | Silent (SNP) | VAF 70/534 reads (13%) | called by muse, mutect2, varscan2
- SVIL | c.6489G>A p.L2163= (on ENST00000355867 / NM_021738.3; = p.L1737= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 180/560 reads (32%) | catalogued as rs778516566; called by muse, mutect2, varscan2
- USP6NL | c.1587C>T p.N529= | Silent (SNP) | VAF 191/420 reads (45%) | catalogued as rs970209029, COSV53214667; called by muse, mutect2, varscan2
- ZDBF2 | c.3310C>T p.L1104= | Silent (SNP) | VAF 76/439 reads (17%) | catalogued as COSV100984731; called by muse, mutect2, varscan2
- ARMC8 | c.1134+124A>G | Intron (SNP) | VAF 89/197 reads (45%) | called by muse, mutect2, varscan2
- F2RL1 | c.*47T>C | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- LMO7 | c.322-15C>T | Intron (SNP) | VAF 124/229 reads (54%) | called by muse, mutect2, varscan2
- NHSL2 | c.-323C>A | 5'UTR (SNP) | VAF 195/451 reads (43%) | called by muse, mutect2, varscan2
- OR8H1 | c.*36C>T | 3'UTR (SNP) | VAF 23/163 reads (14%) | catalogued as rs753365115; called by muse, mutect2, varscan2
- PDXK | c.*11G>A | 3'UTR (SNP) | VAF 61/124 reads (49%) | catalogued as rs369876857; called by muse, varscan2
- SGCE | c.1146-80C>G | Intron (SNP) | VAF 12/67 reads (18%) | catalogued as COSV56021711; called by muse, mutect2, varscan2
- ZNF570 | c.*56C>T | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, varscan2
